CCDI case PBBXLM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/dcc6eda8-0e31-4121-bf98-44745d042cac

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Mucoepidermoid carcinoma: ICD-O-3 morphology code: 8430/3; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 17.2 years (6,270 days).

Biospecimens (3 samples)
- Sample 0DJPCQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJPCW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJPDC: Tissue type: Tumor; Specimen type: Solid Tissue.
